Surgical pathology report (de-identified scan), TCGA case TCGA-39-5016, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5016-01A (Primary Tumor).

[page 1 of 6]
TCGA-39-5016

Clinical Diagnosis & History:

with newly diagnosed right lung carcinoma.

Specimens Submitted:

- 1: SP: Left level 4 mediastinal lymph nodes
- 2: SP: Level seven mediastinal lymph node
- 3: SP: Right level 4 mediastinal lymph node
- 4: SP: Level seven lymph node
- 5: SP: Level 9 lymph node
- 6: SP: Level seven mediastinal lymph nodes #3
- 7: SP: Level seven mediastinal lymph nodes #4
- 8: SP: Right lung
- 9: SP: Portion of pericardium
- 10: SP: Rt. level 4 mediastinal lymph nodes #2

DIAGNOSIS:

- 1) LYMPH NODE, LEVEL IV, MEDIASTINAL; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 2) LYMPH NODE, LEVEL VII, MEDIASTINAL; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 3) LYMPH NODE, LEVEL IV, RIGHT MEDIASTINAL; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODE, LEVEL VII, MEDIASTINAL; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 5) LYMPH NODE, LEVEL IX, MEDIASTINAL; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODE, LEVEL VII, #3; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODE, LEVEL VII, #4; BIOPSY:
- BENIGN ANTHRACOTIC LYMPH NODE.
- 8) LUNG, RIGHT; PNEUMONECTOMY;

** Continued on next page **

[page 2 of 6]
- SQUAMOUS CELL CARCINOMA OF THE RIGHT LOWER LOBE, POORLY DIFFERENTIATED, WITH BASALOID FEATURES.

- THE TUMOR'S GREATEST DIAMETER IS 5.0 CM.
- PERINEURAL INVASION IS PRESENT.
- THE MAINSTEM BRONCHUS IS INVOLVED BY INVASIVE CARCINOMA.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PLEURA IS FREE OF TUMOR.
- THE TUMOR FOCALLY EXTENDS TO AN INKED HILAR SOFT TISSUE MARGIN.
- THE NON-NEOPLASTIC LUNG IS UNREMARKABLE.
- METASTATIC CARCINOMA IN REGIONAL LYMPH NODES. THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): PERIBRONCHIAL - 6/9; PARENCHYMAL - 1/1. DIRECT TUMOR EXTENSION INTO LYMPH NODES IS FOCALLY PRESENT.

- 9) SOFT TISSUE, PERICARDIUM; BIOPSY:
- BENIGN MESOTHELIAL-LINED FIBROADIPOSE TISSUE.
- NO TUMOR SEEN.
- 10) LYMPH NODE, LEVEL IV, #2, RIGHT MEDIASTINAL; BIOPSY:
- BENIGN ANTHRACOTIC LYMPH NODE (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1) The specimen is received fresh for frozen, labeled "Left level 4 mediastinal lymph nodes". It consists of a 0.3 x 0.2 x 0.1 cm portion of pink soft tissue. The specimen is entirely frozen.

Summary of Sections:
PSC - frozen section control

2) The specimen is received fresh for frozen, labeled "Level seven mediastinal lymph node". It consists of a 0.6 x 0.3 x 0.2 cm portion of pink soft tissue. The specimen is entirely frozen. The frozen remnant is submitted for permanents.

Summary of Sections:
PSC - frozen section control

** Continued on next page **

[page 3 of 6]
3) The specimen is received fresh for frozen, labeled "Right level 4 mediastinal lymph node". It consists of a 1.0 x 0.8 x 0.2 cm portion of adipose tissue. The specimen is entirely frozen. The frozen remanent is submitted for permanent sections.

4) The specimen is received fresh for frozen, labeled "Level seven lymph node". It consists of 0.4 x 0.2 x 0.2 cm tan soft tissue fragment. The specimen is entirely frozen. The frozen remanent is submitted for permanent.

Summary of Sections:
FSC - frozen section control

5) Specimen is received fresh for frozen section as a station labeled, "Level 9 lymph node" and consists of fragments of soft tissue measuring 1 x 0 x 7 x 0.2 cm. Specimens have been submitted for frozen section.

Summary of sections:
FSC-frozen section control

6) The specimen is received fresh for frozen, labeled "Level seven mediastinal lymph nodes #3". It consists of a 1.2 x 0.6 x 0.4 cm portion of tan-pink soft tissue. The specimen is entirely submitted. The frozen remanent is submitted for permanent.

Summary of Sections:
FSC - frozen section control

7) The specimen is received fresh for frozen, labeled "Level seven mediastinal lymph nodes #4". It consists of 1.5 x 1.1 x 0.5 cm portion of tan-pink soft tissue. The specimen is entirely frozen. The frozen remanent is submitted for permanents.

Summary of Sections:
FSC - frozen section control

8) The specimen is received fresh for frozen section, labeled "Right lung. Mark bronchial margin". It consists of a 22 x 17 x 5 cm right lung with a tan-pink to gray pleural surface. No pleural adhesions or thickenings are identified. There is an area of firmness and induration in

** Continued on next page **

[page 4 of 6]
the anterior aspect of the hilum, with extension into the pleura and the fissure between the middle and lower-inferior lobes. This area is inked and the pleura between the middle and lower lobes is inked blue. The specimen is serially sectioned to reveal a 5.0 x 3.5 x 3.5 cm tan-pink, firm tumor mass surrounding the right lower lobe bronchus with extension around the main bronchus and the right upper lobe to 1.5 cm from the bronchial margin. The tumor grossly involves peribronchial lymph nodes. The rest of the lung tissue is grossly unremarkable. Tissue is given for TPS.

Summary of Sections:

FSC - Frozen section control of the bronchial margin
TL - Tumor and adjacent lung tissue
TB - Tumor and bronchial wall
THM - Tumor and the hilar aspect of the lung
TP - Tumor and overlying pleura of the interlobar space
LN - Peribronchial lymph nodes
RUL - Representative sections of the right upper lobe
RML - Representative sections of the right middle lobe
RLL - Representative sections of the right lower lobe

9) The specimen is received in formalin, labeled "Portion of pericardium". It consists of a 1.5 x 0.5 x 0.2 cm tan-brown fibrofatty tissue fragment. The specimen is entirely submitted in one cassette.

Summary of Sections:

PC - Pericardium

10) The specimen is received in formalin, labeled "Right level 4 mediastinal lymph nodes #2". It consists of a 1.7 x 0.9 x 0.6 cm tan-pink, rubbery lymph node. The specimen is bisected and entirely submitted in one cassette.

Summary of Sections:

BLN - bisected lymph node

Summary of Sections:

Part 1: SP: Left level 4 mediastinal lymph nodes

Block	Sect.	Site	PCs
1		FSC	1

Part 2: SP: Level seven mediastinal lymph node

** Continued on next page **

[page 5 of 6]
Block Sect. Site PCs
1 FSC 1

Part 3: SP: Right level 4 mediastinal lymph node [REDACTED] [REDACTED]

Block Sect. Site PCs
1 FSC 1

Part 4: SP: Level seven lymph node [REDACTED] [REDACTED]

Block Sect. Site PCs
1 FSC 1

Part 5: SP: Level 9 lymph node [REDACTED] [REDACTED]

Block Sect. Site PCs
1 FSC 1

Part 6: SP: Level seven mediastinal lymph nodes #3 [REDACTED] [REDACTED]

Block Sect. Site PCs
1 FSC 1

Part 7: SP: Level seven mediastinal lymph nodes #4 [REDACTED] [REDACTED]

Block Sect. Site PCs
1 FSC 1

Part 8: SP: Right lung (fs) (t1)

Block	Sect. Site	PCs
1	FSC	1
2	LN	4
1	RLL	1
1	RML	1
1	RUL	1
4	TB	4
3	THM	3
3	TL	3
2	TP	2

Part 9: SP: Portion of pericardium [REDACTED]

Block Sect. Site PCs
1 PC 1

Part 10: SP: Rt. level 4 mediastinal lymph nodes #2 [REDACTED]

Block Sect. Site PCs
1 BLN 2

Intraoperative Consultation:

** Continued on next page **

[page 6 of 6]
Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: NO TUMOR IDENTIFIED. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: NO TUMOR IDENTIFIED. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: NO TUMOR IDENTIFIED. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS: NEGATIVE. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 5) FROZEN SECTION DIAGNOSIS: NO TUMOR IDENTIFIED. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 6) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 7) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 8) FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- [REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file d520766f-62bc-4989-8109-8768861f6b29 (TCGA-39-5016.7B50FFBC-010E-415B-8D85-B5639801E287.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).